Somatic mutation profile of tumor specimen MMRF_2485_1_BM_CD138pos (aliquot MMRF_2485_1_BM_CD138pos_T1_KHS5U_K15195) from MMRF case MMRF_2485, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,150 days).
Specimen MMRF_2485_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcae7c03-c9e8-4086-86a7-2f784d6f1b1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2485_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2485_2_PB_Whole_C1_KHS5U_K15196; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3074e41-b44d-4907-b60e-3deabbab02fe

The open-access MAF lists 72 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 23, Silent 9, Intron 6, 3'Flank 3, 5'Flank 2, 5'UTR 2, Splice Region 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 60/139 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 41/80 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHRNA10 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765656579, COSV51705145; called by muse, varscan2
- CLCA4 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV55366440; called by muse, mutect2, varscan2
- CWF19L1 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 144/306 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs756636089; called by muse, mutect2, varscan2
- FAT4 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101271764, COSV67897987; called by muse, mutect2, varscan2
- FBN2 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541842635, CM148688, COSV52521856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO7 | c.2881A>C p.I961L | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV65686515; called by muse, mutect2, varscan2
- POLA1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 139/174 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765435738; called by muse, varscan2
- PTPRD | c.3253C>A p.L1085M | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61925176; called by muse, mutect2, varscan2
- SALL3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs1197931609; called by muse, mutect2, varscan2
- SHANK2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs894359113; called by muse, mutect2, varscan2
- ANKAR | c.2585G>T p.R862I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- BRWD1 | c.3514G>A p.G1172S | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FN1 | c.5615-5C>A | Splice Region (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- JMJD1C | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- KIF15 | c.3473C>T p.T1158I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MBD5 | c.2237C>G p.S746C | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- MPDZ | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYCBP2 | c.3729_3729+4del p.X1243_splice (on ENST00000357337; = p.X1281_splice on NM_015057.5) | Splice Site (DEL) | VAF 28/65 reads (43%) | called by mutect2, pindel
- OR2L5 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PAIP2 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 23/718 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- PCDHA3 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PIK3C2G | c.4269A>T p.K1423N (on ENST00000676171; = p.K1382N on NM_004570.5) | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RGS7BP | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TGM6 | c.2050G>C p.V684L | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- VPS45 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ECM2 | c.375C>T p.L125= | Silent (SNP) | VAF 70/135 reads (52%) | called by muse, mutect2, varscan2
- FSTL5 | c.1137T>C p.I379= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.333G>A p.Q111= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs557431006; called by muse, varscan2
- IGLL5 | c.45G>A p.E15= | Silent (SNP) | VAF 55/96 reads (57%) | catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, mutect2, varscan2
- PDSS1 | c.1143G>A p.Q381= | Silent (SNP) | VAF 142/379 reads (37%) | catalogued as rs201068515; called by muse, mutect2, varscan2
- PRMT3 | c.564A>G p.Q188= | Silent (SNP) | VAF 60/258 reads (23%) | catalogued as rs747641099; called by muse, varscan2
- RIPK4 | c.1128C>T p.N376= (on ENST00000352483; = p.N328= on NM_020639.3) | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs368623411; called by muse, mutect2, varscan2
- WDR97 | c.1209G>A p.A403= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as rs1197773678; called by muse, mutect2, varscan2
- ZNF335 | c.1140A>C p.G380= | Silent (SNP) | VAF 17/244 reads (7%) | called by muse, mutect2
- ACTG1 | c.363+101C>T | Intron (SNP) | VAF 18/45 reads (40%) | catalogued as rs782700031; called by muse, mutect2, varscan2
- AFG1L | c.*2219G>A | 3'UTR (SNP) | VAF 75/159 reads (47%) | catalogued as rs977148598; called by muse, mutect2, varscan2
- AKR7L | c.215-10T>G | Intron (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- AP3B1 | c.*315A>G | 3'UTR (SNP) | VAF 40/77 reads (52%) | catalogued as rs1561346087; called by muse, mutect2, varscan2
- ASAH1 | c.*825C>A | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 78/169 reads (46%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- CARTPT | c.*219C>G | 3'UTR (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- CHRNA7 | c.196-31T>C | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- CNIH3 | c.*355A>G | 3'UTR (SNP) | VAF 62/123 reads (50%) | catalogued as rs1171019554; called by muse, varscan2
- COA1 | c.-38-447T>C | Intron (SNP) | VAF 68/126 reads (54%) | called by muse, mutect2, varscan2
- CTXN2 | c.*2097T>G | 3'UTR (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- CXorf56 | chrX:119539079 T>C | 3'Flank (SNP) | VAF 17/17 reads (100%) | called by muse, mutect2, varscan2
- CYP7A1 | c.*226T>C | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- DGCR8 | c.*864C>T | 3'UTR (SNP) | VAF 53/99 reads (54%) | catalogued as rs1432974966; called by muse, mutect2, varscan2
- EMP2 | c.*2961_*2962insC | 3'UTR (INS) | VAF 12/23 reads (52%) | called by mutect2, varscan2
- FAM110C | c.*222T>C | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- FAM13A | c.*2011C>T | 3'UTR (SNP) | VAF 71/142 reads (50%) | catalogued as rs748736524; called by muse, mutect2, varscan2
- FEM1B | c.*2061G>A | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- GABRB3 | c.-67G>A | 5'UTR (SNP) | VAF 94/153 reads (61%) | called by muse, mutect2, varscan2
- GPR27 | c.*1214T>G | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- H2BC15 | chr6:27837933 C>T | 5'Flank (SNP) | VAF 175/374 reads (47%) | called by muse, mutect2, varscan2
- HOXD11 | c.*153C>T | 3'UTR (SNP) | VAF 92/174 reads (53%) | catalogued as rs1207306594; called by muse, mutect2, varscan2
- KCNB2 | c.*45A>T | 3'UTR (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- KIAA1217 | c.*995A>T | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*2757C>T | 3'UTR (SNP) | VAF 41/76 reads (54%) | catalogued as rs1489902991; called by muse, mutect2, varscan2
- KREMEN1 | chr22:29145186 G>A | 3'Flank (SNP) | VAF 86/165 reads (52%) | catalogued as rs888587702; called by muse, varscan2
- MAPRE2 | c.250+65A>C | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- NAF1 | chr4:163126829 G>A | 3'Flank (SNP) | VAF 65/171 reads (38%) | called by muse, mutect2, varscan2
- NSMF | c.-217C>T | 5'UTR (SNP) | VAF 12/26 reads (46%) | catalogued as rs1022730593; called by mutect2, varscan2
- PAPOLB | c.*1191A>G | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- PDK3 | c.*334C>T | 3'UTR (SNP) | VAF 45/57 reads (79%) | called by muse, mutect2, varscan2
- PRUNE2 | c.*2269_*2270dup | 3'UTR (INS) | VAF 18/52 reads (35%) | catalogued as rs1554753127; called by mutect2, varscan2
- SSTR2 | c.*251G>C | 3'UTR (SNP) | VAF 93/182 reads (51%) | called by muse, mutect2, varscan2
- WAC | c.*129G>A | 3'UTR (SNP) | VAF 108/256 reads (42%) | called by muse, mutect2, varscan2
- WWTR1 | c.*827G>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs1227823987; called by muse, varscan2
- ZNF726 | c.1836+50G>A | Intron (SNP) | VAF 77/171 reads (45%) | called by muse, mutect2, varscan2
